Gene-level copy-number profile of tumor specimen TCGA-61-2095-02A from TCGA case TCGA-61-2095, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 54.2 years (19,797 days).
Specimen TCGA-61-2095-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e49f394f-9548-4187-9ecd-04cb3fb5d238.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2095-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 391 have no estimate.
https://portal.gdc.cancer.gov/files/38b7655d-9894-4731-9dac-c2382666a267

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 624; copy number 1: 5,335; copy number 2: 50,397; copy number 3: 2,635; copy number 4: 1,161; copy number 6: 79; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 104 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr3:103,630,661–103,630,912, 1 gene: TUBBP11.
- chr4:10,167,159–10,200,672, 2 genes: AC006499.6, AC006499.1.
- chr9:20,341,669–26,644,595, 90 genes (within-gene range 0–1) (broad region; genes not listed).
- chr11:124,302,831–124,405,102, 10 genes: OR8D1, OR8D2, OR8B7P, OR8B6P, OR8B5P, OR8B1P, OR8C1P, OR8B2, OR8B3, OR8X1P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 80 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:80,972,516–80,974,724, 1 gene, copy number 6: AC004972.1.
- chr17:18,809,956–19,978,343, 78 genes, copy number 6 (broad region; genes not listed).
- chr21:23,079,284–23,079,392, 1 gene, copy number 11: MIR6130.

Autosomal genes at a single copy (total copy number 1): 5,219. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
